Somatic mutation profile of tumor specimen MMRF_1436_1_BM_CD138pos (aliquot MMRF_1436_1_BM_CD138pos_T1_KAS5U_L01379) from MMRF case MMRF_1436, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.4 years (23,530 days).
Specimen MMRF_1436_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8e4c16c-9187-48fb-a6be-e9ffd0c633bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1436_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1436_1_PB_Whole_C2_KAS5U_L01391; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c721d9d3-3cd1-4ded-8ecc-378bee4c2d57

The open-access MAF lists 79 somatic variants for this specimen: 35 protein-altering or splice-affecting, 4 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 27, Intron 8, Silent 4, Frame Shift Del 3, Nonsense Mutation 2, 5'Flank 2, 5'UTR 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 59/121 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCA12 | c.4664T>C p.L1555P (on ENST00000272895 / NM_173076.3; = p.L1237P on NM_015657.3) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55958566; called by muse, mutect2, varscan2
- ABTB2 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs966509865; called by muse, mutect2, varscan2
- ACADL | c.1228A>G p.I410V | Missense Mutation (SNP) | VAF 104/247 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as rs775497317; called by muse, mutect2, varscan2
- APC | c.6123A>C p.E2041D | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1554087227; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLASP2 | c.590_591del p.H197Rfs*11 | Frame Shift Del (DEL) | VAF 149/569 reads (26%) | catalogued as rs779022068; called by mutect2, pindel, varscan2
- CNIH4 | c.246A>G p.I82M | Missense Mutation (SNP) | VAF 127/316 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs1461458883, COSV64795979; called by muse, mutect2, varscan2
- EPHA5 | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 116/257 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777838691, COSV56653935; called by muse, mutect2, varscan2
- GAS2 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 100/163 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1372094047, COSV53410207; called by muse, mutect2, varscan2
- H2BC17 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs565479130; called by muse, mutect2, varscan2
- HOXC13 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as COSV54499297; called by muse, mutect2, varscan2
- IGHV2-70 | c.219T>G p.D73E | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs181059057; called by muse, varscan2
- IGHV2-70 | c.191A>G p.K64R | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs549292393; called by muse, varscan2
- IGKV4-1 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 24/27 reads (89%) | catalogued as rs1481232905; called by muse, mutect2, varscan2
- LRAT | c.686C>A p.A229D | Missense Mutation (SNP) | VAF 246/533 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1413244862, COSV60477573; called by muse, mutect2, varscan2
- NGEF | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as rs1225956662; called by muse, mutect2, varscan2
- OR5J2 | c.419A>C p.K140T | Missense Mutation (SNP) | VAF 97/139 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as COSV100399134; called by muse, mutect2, varscan2
- OR6S1 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100289341; called by muse, mutect2, varscan2
- PDGFD | c.791A>G p.N264S | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as rs1195913329; called by muse, mutect2, varscan2
- SYNDIG1 | c.707T>C p.I236T | Missense Mutation (SNP) | VAF 110/270 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs749966226; called by muse, mutect2, varscan2
- TMEM161B | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as COSV99680890; called by muse, mutect2, varscan2
- C2CD5 | c.1789A>G p.I597V | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- CEP250 | c.4058del p.L1353Rfs*13 | Frame Shift Del (DEL) | VAF 34/102 reads (33%) | called by mutect2, pindel, varscan2
- CFAP161 | c.730G>C p.A244P | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- E2F2 | c.130T>C p.Y44H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HEATR5A | c.13C>G p.H5D | Missense Mutation (SNP) | VAF 142/370 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV2-70D | c.128T>G p.F43C | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, varscan2
- MTMR6 | c.449A>C p.N150T | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR52E5 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 93/274 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- OTUD7A | c.1015_1021+2del p.X339_splice (on ENST00000307050 / NM_001382637.1; = p.X332_splice on NM_130901.3) | Splice Site (DEL) | VAF 159/322 reads (49%) | called by mutect2, pindel, varscan2
- RAD9B | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- SLC35G1 | c.63C>A p.D21E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SP140 | c.1361_1362del p.C454Ffs*21 | Frame Shift Del (DEL) | VAF 50/147 reads (34%) | called by pindel, varscan2
- TRIM71 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.7817C>A p.A2606E (on ENST00000591111; = p.A2560E on NM_003319.4) | Missense Mutation (SNP) | VAF 39/98 reads (40%) | PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IGHV2-70 | c.252G>A p.L84= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as rs374732396; called by muse, varscan2
- IGKV4-1 | c.207T>C p.P69= | Silent (SNP) | VAF 49/58 reads (84%) | catalogued as rs373552807; called by muse, mutect2, varscan2
- POLR3D | c.531T>C p.P177= | Silent (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- SHANK1 | c.4635G>T p.L1545= | Silent (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- ATP11A | c.*1135C>T | 3'UTR (SNP) | VAF 44/88 reads (50%) | catalogued as rs907477793; called by muse, mutect2
- C10orf53 | c.*449A>C | 3'UTR (SNP) | VAF 95/195 reads (49%) | called by muse, mutect2, varscan2
- CASKIN2 | c.930+122_930+124del | Intron (DEL) | VAF 21/50 reads (42%) | catalogued as rs1189996521; called by pindel, varscan2
- CFAP46 | c.*6C>T | 3'UTR (SNP) | VAF 85/194 reads (44%) | catalogued as COSV99584002, COSV99584798; called by muse, mutect2, varscan2
- COL4A1 | c.*68C>T | 3'UTR (SNP) | VAF 191/456 reads (42%) | catalogued as COSV65424101, COSV65427825; called by muse, mutect2, varscan2
- COX20 | c.*13_*14insCAGAA | 3'UTR (INS) | VAF 30/196 reads (15%) | catalogued as rs762438072; called by mutect2, varscan2
- CYP2A7 | c.1161+28C>T | Intron (SNP) | VAF 22/122 reads (18%) | catalogued as rs777409361; called by muse, mutect2, varscan2
- DPP10 | c.*557T>A | 3'UTR (SNP) | VAF 34/86 reads (40%) | called by muse, mutect2, varscan2
- DPP10 | c.*2547T>G | 3'UTR (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- FAM102B | c.556+80G>T | Intron (SNP) | VAF 70/209 reads (33%) | called by muse, mutect2, varscan2
- FANCI | c.*492G>T | 3'UTR (SNP) | VAF 43/141 reads (30%) | catalogued as COSV51520671; called by muse, mutect2, varscan2
- FAT4 | c.*670A>T | 3'UTR (SNP) | VAF 47/102 reads (46%) | called by muse, mutect2, varscan2
- LYSMD4 | c.*546T>G | 3'UTR (SNP) | VAF 62/97 reads (64%) | called by muse, mutect2, varscan2
- MASP1 | c.1091-3017C>A | Intron (SNP) | VAF 38/137 reads (28%) | called by muse, mutect2, varscan2
- MLXIP | c.*1704A>G | 3'UTR (SNP) | VAF 52/123 reads (42%) | called by muse, mutect2, varscan2
- MPPED2 | c.*2063G>A | 3'UTR (SNP) | VAF 34/148 reads (23%) | called by muse, mutect2, varscan2
- MYO1E | c.-19G>A | 5'UTR (SNP) | VAF 10/48 reads (21%) | catalogued as rs532748683; called by muse, varscan2
- MYO1E | c.-153T>C | 5'UTR (SNP) | VAF 28/84 reads (33%) | called by muse, varscan2
- NADK | c.*596A>T | 3'UTR (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- NRXN1 | c.*1575A>C | 3'UTR (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- PCDH17 | c.*3043A>C | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- PLOD1 | c.580-455A>T | Intron (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- QSOX1 | c.*1876G>T | 3'UTR (SNP) | VAF 47/113 reads (42%) | called by muse, mutect2, varscan2
- RBM24 | c.*996T>G | 3'UTR (SNP) | VAF 82/166 reads (49%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.*1256C>T | 3'UTR (SNP) | VAF 72/144 reads (50%) | catalogued as rs1028494141; called by muse, mutect2, varscan2
- SERPINB2 | c.*180A>T | 3'UTR (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2, varscan2
- SLC16A10 | c.*935T>C | 3'UTR (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- SLC34A1 | c.841-40C>T | Intron (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- SMAP2 | c.*796_*807del | 3'UTR (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- SORD | c.908+14G>A | Intron (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- SSPOP | n.11498C>T | RNA (SNP) | VAF 14/36 reads (39%) | catalogued as rs748338397; called by muse, mutect2, varscan2
- SYBU | chr8:109647616 T>C | 5'Flank (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- TCF7L2 | c.*686T>A | 3'UTR (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- THAP2 | c.*3492dup | 3'UTR (INS) | VAF 56/119 reads (47%) | catalogued as rs1264256310; called by mutect2, varscan2
- TIPARP | c.*7T>A | 3'UTR (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99903991; called by muse, mutect2, varscan2
- TMEM19 | c.*971G>A | 3'UTR (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- TMEM198 | c.*436C>T | 3'UTR (SNP) | VAF 35/76 reads (46%) | catalogued as rs907468937; called by muse, mutect2, varscan2
- TRPA1 | c.*1523C>T | 3'UTR (SNP) | VAF 20/47 reads (43%) | catalogued as rs891683193; called by muse, mutect2, varscan2
- TSN | chr2:121755556 G>T | 5'Flank (SNP) | VAF 43/79 reads (54%) | called by muse, mutect2, varscan2
- UBAC2 | c.31+466C>A | Intron (SNP) | VAF 67/132 reads (51%) | called by muse, mutect2, varscan2
